Gene-level copy-number profile of tumor specimen C3N-03841-01 (profiled together with C3N-03841-02) from CPTAC case C3N-03841, project CPTAC-3 (Other and ill-defined sites — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 59.5 years (21,732 days).
Specimen C3N-03841-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Supraglottis; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 53b03bec-92e8-4937-b4e1-fe1a12c0fdcb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03841-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/40974ae4-766d-4d98-a325-7d88d1e436bb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 374; copy number 1: 663; copy number 2: 25,866; copy number 3: 25,945; copy number 4: 3,656; copy number 5: 1,050; copy number 6: 55; copy number 7: 127; copy number 8: 433; copy number 10: 65; copy number 11: 4; copy number 12: 334; copy number 14: 16; copy number 15: 255; copy number 18: 3; copy number 20: 25; copy number 22: 26; copy number 24: 11.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,856,389–60,856,605, 1 gene (within-gene range 0–1): U3.
- chr6:32,517,353–32,589,848, 4 genes: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,128,103, 9 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,299 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:154,007,367–158,626,849, 83 genes, copy number 7 (broad region; genes not listed).
- chr7:98,454,119–107,202,522, 265 genes, copy number 12–24 (within-gene range 2–24) (broad region; genes not listed).
- chr11:69,048,932–72,521,733, 116 genes, copy number 10–20 (broad region; genes not listed).
- chr12:12,310–24,562,544, 620 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr12:24,212,421–34,249,958, 213 genes, copy number 12 (broad region; genes not listed).
- chr18:22,413,599–22,419,294, 2 genes, copy number 8: CTAGE1, ATP7BP1.

Autosomal genes at a single copy (total copy number 1): 497. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
